Somatic mutation profile of tumor specimen TCGA-DJ-A13X-01A (aliquot TCGA-DJ-A13X-01A-11D-A10S-08) from TCGA case TCGA-DJ-A13X, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 51.2 years (18,689 days).
Specimen TCGA-DJ-A13X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 551ae777-c205-413b-bfcb-bdaa7fccc304.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A13X-10A (Blood Derived Normal), aliquot TCGA-DJ-A13X-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56fb706e-3d95-40f3-92a9-ec922282fe7f

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C16orf86 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.024); catalogued as COSV54677331; called by muse, mutect2, varscan2
- FAM110C | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100566881, COSV59655660; called by muse, mutect2
- FNDC7 | c.1042T>G p.F348V | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV54757058; called by muse, mutect2
- MYO1E | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV55693580; called by muse, mutect2
- FAM110C | c.798C>G p.G266= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1558182100, COSV100566879; called by muse, mutect2
- CCM2 | c.31-10532G>A | Intron (SNP) | VAF 19/93 reads (20%) | catalogued as rs749387943, COSV51849044; called by muse, mutect2, varscan2
